Somatic mutation profile of tumor specimen ALCH-ADW3-TTP1-A (aliquot ALCH-ADW3-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADW3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.3 years (23,118 days).
Specimen ALCH-ADW3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d3df6b1-13d5-479e-899d-10ed31229a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADW3-NB1-A (Blood Derived Normal), aliquot ALCH-ADW3-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e99e81f-f80c-4865-bd99-da95203c2000

The open-access MAF lists 48 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Intron 3, Nonsense Mutation 3, 3'UTR 3, 3'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 40/682 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2
- CDH9 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 44/874 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2
- CSNK1E | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as rs1555908154; called by muse, mutect2
- DOCK2 | c.1483-1G>T p.X495_splice | Splice Site (SNP) | VAF 28/406 reads (7%) | catalogued as COSV56993454, COSV99909547; called by muse, mutect2
- ERICH3 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV58598628; called by muse, mutect2
- FCGBP | c.6599C>T p.P2200L | Missense Mutation (SNP) | VAF 60/1572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370331745; called by muse, mutect2
- HOXB3 | c.684C>A p.S228R | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57485793; called by muse, mutect2
- PCDH11X | c.2229C>A p.D743E | Missense Mutation (SNP) | VAF 19/447 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53464460; called by muse, mutect2
- SLC45A2 | c.733G>T p.V245F | Missense Mutation (SNP) | VAF 39/645 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs770514854; called by muse, mutect2
- AFF3 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.591); called by muse, mutect2
- BDP1 | c.5857G>C p.E1953Q | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.337); called by muse, mutect2
- CSMD3 | c.9388G>T p.G3130C (on ENST00000297405 / NM_001363185.1; = p.G2961C on NM_052900.3) | Missense Mutation (SNP) | VAF 20/652 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DTNA | c.1773G>T p.Q591H | Missense Mutation (SNP) | VAF 32/676 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- GRM3 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- HNRNPAB | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- HTR1B | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KEAP1 | c.1407T>A p.N469K | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2
- LRP1B | c.12037C>G p.L4013V | Missense Mutation (SNP) | VAF 37/924 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- MKKS | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 35/929 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NLRP13 | c.2359C>G p.L787V | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2T11 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2
- OR4C11 | c.383T>A p.L128* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB10 | c.1286C>G p.P429R | Missense Mutation (SNP) | VAF 24/920 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASA2 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 26/733 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SCARB1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2
- SLC23A2 | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 17/477 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- VN1R2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ZNF311 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- ZNF445 | c.1979A>T p.E660V | Missense Mutation (SNP) | VAF 32/707 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2
- ANKDD1B | c.852C>T p.V284= | Silent (SNP) | VAF 26/433 reads (6%) | called by muse, mutect2
- ANKRD11 | c.642C>T p.Y214= | Silent (SNP) | VAF 46/625 reads (7%) | catalogued as rs771317555; called by muse, mutect2
- ANKS4B | c.42G>A p.L14= | Silent (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- CACNA1D | c.1029C>A p.G343= | Silent (SNP) | VAF 15/428 reads (4%) | catalogued as COSV55463479; called by muse, mutect2
- GHRHR | c.187C>T p.L63= | Silent (SNP) | VAF 24/582 reads (4%) | called by muse, mutect2
- MAGEC1 | c.1723C>T p.L575= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV53570103, COSV53572063; called by muse, mutect2, varscan2
- SLC35B3 | c.1020T>C p.L340= | Silent (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- STAB2 | c.2583T>C p.D861= | Silent (SNP) | VAF 13/304 reads (4%) | catalogued as rs1206227366; called by muse, mutect2
- TARS1 | c.259T>C p.L87= | Silent (SNP) | VAF 29/480 reads (6%) | called by muse, mutect2
- ULK3 | c.168G>A p.V56= | Silent (SNP) | VAF 18/592 reads (3%) | catalogued as rs1443726615; called by muse, mutect2
- CDK11A | chr1:1701181 G>A | 3'Flank (SNP) | VAF 20/538 reads (4%) | catalogued as rs1274205218; called by muse, mutect2
- FAM71F1 | c.*25T>C | 3'UTR (SNP) | VAF 13/448 reads (3%) | called by muse, mutect2
- HOGA1 | c.603+30C>A | Intron (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- SIGLEC1 | c.*80G>T | 3'UTR (SNP) | VAF 17/393 reads (4%) | called by muse, mutect2
- SMAD9 | c.-35G>T | 5'UTR (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- TNFRSF11B | c.401-42G>A | Intron (SNP) | VAF 18/319 reads (6%) | catalogued as rs368532157; called by muse, mutect2
- TRIM8 | c.*708C>T | 3'UTR (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- WDR70 | c.1093-9729T>G | Intron (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
